Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8PZ, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8PZ-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Body)

1- Esophageal margin (paraffin embedded):
- UNINVOLVED BY NEOPLASIA.

2- Product of total gastrectomy:
- ADENOCARCINOMA WITH THE FOLLOWING FEATURES:
* LARGEST SIZE: 13.5 CM;
* PRESENCE OF ULCERATION;
* BORRMANN IV (LINITIS PLASTICA);
* SUBTYPE: MUCOSECRETOR, MUCOCELULAR SIGNET-RING CARCINOMA;
* LAUREN SUBTYPE: DIFFUSE;
* TUMOR INVADES TO SEROSA;
* PRESENCE OF FOCAL NEURAL INVASION;
* LYMPHATIC INVASION NOT OBSERVED;
* VASCULAR INVASION NOT OBSERVED;
* SURGICAL MARGINS UNINVOLVED BY NEOPLASIA;
* PERIVISCERAL LYMPH NODES UNINVOLVED BY METASTASIS (0/14).

3- D2 lymphadenectomy as standard protocol:
- LYMPH NODES UNINVOLVED BY NEOPLASIA (0/54).

4- Gastro-hepatic ligament:
- UNINVOLVED BY NEOPLASIA.

5- Peripancreatic peritoneum:
- UNINVOLVED BY NEOPLASIA.

6- Second esophageal margin:
- UNINVOLVED BY NEOPLASIA.

7- Pancreatic margin:
- UNINVOLVED BY NEOPLASIA.

8- Spleen:
- UNINVOLVED BY NEOPLASIA.

9- Omentum:
- UNINVOLVED BY NEOPLASIA.

ICD-O-3

Adenocarcinoma, signet ring
cell 8490/3

Site: Body of stomach
C16.3
9/3/14

Staging Discrepancy		✓
Local Symptomatology Discrepancy		✓
Local Discrepancy		✓
Review Initials	MA	11/1/13

Source: NCI Genomic Data Commons file d7a95f14-5995-4a52-91fc-dc904e71b146 (TCGA-VQ-A8PZ.94F43EA9-C876-422F-A93B-B1F68FAC1BA8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).